Somatic mutation profile of tumor specimen TCGA-BP-4782-01A (aliquot TCGA-BP-4782-01A-02D-1421-08) from TCGA case TCGA-BP-4782, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.0 years (20,102 days).
Specimen TCGA-BP-4782-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdfda439-a974-40c0-9677-73ad13600971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4782-11A (Solid Tissue Normal), aliquot TCGA-BP-4782-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d907dcf6-9cf3-4c5e-98dd-ed88ed992dab

The open-access MAF lists 87 somatic variants for this specimen: 74 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 58, Silent 13, Frame Shift Del 10, Nonsense Mutation 4, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADTRP | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV57644928, COSV57645614; called by muse, mutect2, varscan2
- APC2 | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.967); catalogued as rs778930760, COSV52020892; called by muse, mutect2, varscan2
- ATXN1 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55226072; called by muse, mutect2, varscan2
- CACNA1G | c.6499T>A p.Y2167N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as COSV61734409; called by muse, mutect2, varscan2
- CDC23 | c.1703C>G p.P568R | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV67510351; called by muse, mutect2, varscan2
- CDH8 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 30/413 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV54887869; called by muse, mutect2
- CDKL5 | c.1935G>C p.L645F | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV66112616; called by muse, mutect2, varscan2
- CELA3A | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV51585915; called by muse, mutect2, varscan2
- CPAMD8 | c.4925A>C p.D1642A (on ENST00000651564; = p.D1595A on NM_015692.5) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as COSV71597185; called by muse, mutect2, varscan2
- CTNNA1 | c.2583G>A p.M861I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57079076; called by muse, mutect2, varscan2
- CUL4B | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60689928; called by muse, varscan2
- CYTH3 | c.194A>C p.Q65P | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV63440413; called by muse, mutect2, varscan2
- DNAH1 | c.4462G>C p.V1488L | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV70233592; called by muse, mutect2, varscan2
- DNAH8 | c.10197T>G p.N3399K | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59449171, COSV59469672; called by muse, mutect2, varscan2
- DNAH9 | c.6204G>T p.Q2068H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV52367129; called by muse, mutect2, varscan2
- EIF4A2 | c.697A>C p.I233L | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV56218143, COSV99961140; called by muse, mutect2, varscan2
- FAM221A | c.693C>A p.F231L | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV61388337; called by muse, mutect2, varscan2
- FANCG | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763387428, COSV62721298; called by muse, mutect2
- FANCG | c.1556G>C p.S519T | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.681); catalogued as COSV62721722; called by muse, mutect2
- FMOD | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.718); catalogued as rs759333337, COSV61610467; called by muse, mutect2, varscan2
- FRY | c.8017C>A p.Q2673K | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as COSV66575991; called by muse, mutect2, varscan2
- GBA2 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62306560; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.395); catalogued as COSV61323914; called by muse, mutect2, varscan2
- GPR15 | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV52521090; called by muse, mutect2, varscan2
- ITPR2 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 66/458 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.78); catalogued as COSV67274060; called by muse, varscan2
- KAT2B | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV55432851; called by muse, mutect2, varscan2
- KCTD14 | c.513C>A p.C171* | Nonsense Mutation (SNP) | VAF 56/312 reads (18%) | catalogued as COSV62001925; called by muse, mutect2, varscan2
- KIF21A | c.2398A>C p.K800Q (on ENST00000361418 / NM_001378440.1; = p.K787Q on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62775971; called by muse, mutect2, varscan2
- KIF2B | c.1970del p.K657Rfs*3 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | catalogued as COSV52127958; called by mutect2, pindel, varscan2
- KLF3 | c.72T>G p.N24K | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV54712005; called by muse, mutect2, varscan2
- KRT4 | c.442T>C p.F148L | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53408977; called by muse, mutect2
- LHX8 | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 15/308 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as COSV53958841; called by muse, mutect2
- LIPF | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV53285639; called by muse, mutect2, varscan2
- LRRC4 | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50816719; called by muse, mutect2, varscan2
- LYST | c.8108A>G p.K2703R | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV67711441; called by muse, mutect2
- MAB21L1 | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV59809279; called by muse, mutect2, varscan2
- MED25 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57206384; called by muse, mutect2, varscan2
- MRPS17 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 115/494 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as COSV53392788; called by muse, mutect2, varscan2
- NHSL2 | c.749A>C p.D250A (on ENST00000510661; = p.D616A on NM_001013627.2) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65454438; called by muse, mutect2, varscan2
- NKAP | c.217C>A p.R73S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.186); catalogued as COSV65056737; called by muse, mutect2, varscan2
- NYAP2 | c.1392C>A p.S464R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56013032; called by muse, mutect2, varscan2
- NYAP2 | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.419); catalogued as COSV55999275, COSV56013054; called by muse, mutect2, varscan2
- OPTC | c.731G>C p.R244T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs749718010, COSV65868371; called by muse, mutect2, varscan2
- PLCL1 | c.1166T>G p.F389C | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70858209; called by muse, varscan2
- PLD1 | c.2987C>A p.T996K | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as COSV60572296; called by muse, mutect2, varscan2
- PRAME | c.1439T>C p.V480A | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV67160828; called by muse, mutect2, varscan2
- PRELP | c.957C>A p.N319K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV58117041; called by muse, mutect2, varscan2
- PRRC2B | c.3790G>C p.D1264H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs1453087838, COSV61941378; called by muse, mutect2, varscan2
- QRICH2 | c.3866G>A p.R1289Q | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs564431023, COSV53153567; called by muse, mutect2, varscan2
- RABGEF1 | c.536G>C p.G179A (on ENST00000439720 / NM_001287061.2; = p.G166A on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53164080; called by muse, mutect2, varscan2
- RIMS1 | c.2573T>A p.L858* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV53474000; called by muse, mutect2
- RIPK4 | c.1277A>T p.D426V (on ENST00000352483; = p.D378V on NM_020639.3) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV60189618; called by muse, mutect2, varscan2
- RP1L1 | c.6210G>C p.E2070D | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.175); catalogued as COSV66758584; called by muse, mutect2, varscan2
- RPA3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs749246644, COSV56189411; called by muse, mutect2, varscan2
- RPL7 | c.264A>T p.K88N | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV53583730; called by muse, mutect2, varscan2
- SLC52A1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as rs1435671378, COSV54693500; called by muse, mutect2, varscan2
- SPSB3 | c.721G>C p.G241R | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51601153; called by muse, mutect2, varscan2
- STAT2 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 47/131 reads (36%) | catalogued as COSV58475951; called by muse, mutect2, varscan2
- TENT5D | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 33/384 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV57638379; called by muse, mutect2
- TMEM80 | c.427G>C p.V143L (on ENST00000526170 / NM_001276274.1; = p.V205L on NM_174940.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.096); catalogued as COSV104404054, COSV59349576; called by muse, mutect2, varscan2
- TNR | c.1429G>C p.G477R | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54904513; called by muse, mutect2, varscan2
- TRAPPC9 | c.1623-1G>A p.X541_splice | Splice Site (SNP) | VAF 39/212 reads (18%) | catalogued as COSV66906716; called by muse, mutect2, varscan2
- TTN | c.90643del p.R30215Vfs*13 (on ENST00000591111; = p.R22791Vfs*13 on NM_003319.4) | Frame Shift Del (DEL) | VAF 150/810 reads (19%) | catalogued as COSV60188735; called by mutect2, pindel, varscan2
- ZNF17 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV56922155; called by muse, mutect2, varscan2
- ABTB2 | c.1945del p.E649Rfs*3 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- ALG13 | c.584del p.L195Pfs*23 | Frame Shift Del (DEL) | VAF 36/185 reads (19%) | called by mutect2, pindel, varscan2
- CAPN1 | c.1268_1272del p.L423Pfs*39 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- CCDC173 | c.573del p.N192Tfs*28 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | called by mutect2, pindel
- PYCARD | c.276_280delinsAT p.S93_G94delins* | Nonsense Mutation (DEL) | VAF 7/34 reads (21%) | called by pindel, varscan2*
- RAB8A | c.185+1del | Frame Shift Del (DEL) | VAF 18/128 reads (14%) | called by mutect2, pindel, varscan2
- RFX7 | c.412del p.S138Afs*10 (on ENST00000559447 / NM_001368074.1; = p.S235Afs*10 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- TMEM185A | c.713A>T p.H238L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.324); called by muse, mutect2
- UNK | c.1800del p.N600Kfs*15 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- URB2 | c.526del p.A176Pfs*7 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- APOBEC3F | c.240T>A p.P80= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as COSV57911512; called by muse, mutect2, varscan2
- CD93 | c.331C>T p.L111= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV55667655; called by muse, mutect2, varscan2
- CYP27B1 | c.1038G>A p.E346= | Silent (SNP) | VAF 54/315 reads (17%) | catalogued as COSV56986039; called by muse, mutect2, varscan2
- HECW1 | c.2676T>C p.I892= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as COSV67836835; called by muse, mutect2, varscan2
- MYH7 | c.3183G>T p.L1061= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV62522148; called by muse, mutect2, varscan2
- NCL | c.1689A>G p.S563= | Silent (SNP) | VAF 33/197 reads (17%) | catalogued as rs1240214837, COSV59546271, COSV59547067; called by muse, mutect2, varscan2
- PPL | c.210G>T p.V70= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV62049546; called by muse, mutect2, varscan2
- RAD54L | c.2163G>A p.Q721= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1211113211, COSV58441533; called by muse, mutect2
- RBM39 | c.1471T>C p.L491= (on ENST00000253363 / NM_001323424.2; = p.L485= on NM_004902.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/283 reads (20%) | catalogued as rs1256132721, COSV53616942; called by muse, mutect2, varscan2
- TMEM208 | c.357T>A p.S119= | Silent (SNP) | VAF 42/284 reads (15%) | catalogued as COSV50765979; called by muse, mutect2, varscan2
- TMUB2 | c.393G>A p.E131= (on ENST00000538716 / NM_001353177.2; = p.E111= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs1292829699, COSV60229588; called by muse, mutect2, varscan2
- UNK | c.1512C>T p.F504= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV53140120; called by muse, mutect2
- WDFY2 | c.354G>C p.T118= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV53291939; called by muse, mutect2, varscan2
